Somatic mutation profile of tumor specimen ALCH-ADUZ-TTR1-A (aliquot ALCH-ADUZ-TTR1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-ADUZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,585 days).
Specimen ALCH-ADUZ-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46de31fd-af6d-41ab-9bf6-cddb06576515.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUZ-NB1-A (Blood Derived Normal), aliquot ALCH-ADUZ-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/239707fb-b7f4-4de3-a9d5-30e3253f6b35

The open-access MAF lists 415 somatic variants for this specimen: 279 protein-altering or splice-affecting, 75 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 75, Intron 39, Nonsense Mutation 14, RNA 8, Frame Shift Del 8, 3'UTR 6, Splice Region 5, Splice Site 5, 5'UTR 4, 5'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 187/268 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13451G>C p.G4484A | Missense Mutation (SNP) | VAF 124/574 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68949361; called by muse, mutect2, varscan2
- ACBD5 | c.1126G>A p.E376K (on ENST00000375888 / NM_001352568.1; = p.E367K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/454 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV101022586; called by muse, mutect2, varscan2
- ACSM1 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54639282; called by muse, mutect2, varscan2
- ADAT1 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV57189132; called by muse, mutect2, varscan2
- ADGB | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV58855321; called by muse, varscan2
- ADGRL3 | c.3420C>A p.I1140= (on ENST00000506720 / NM_001322402.2; = p.I1072= on NM_015236.6) | Splice Region (SNP) | VAF 91/137 reads (66%) | catalogued as COSV72230149; called by muse, mutect2, varscan2
- AGTPBP1 | c.1804G>T p.D602Y (on ENST00000357081 / NM_001330701.2; = p.D562Y on NM_015239.2) | Missense Mutation (SNP) | VAF 113/496 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1174496041; called by muse, mutect2, varscan2
- ANP32E | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 234/917 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV100029796; called by muse, mutect2, varscan2
- ARHGAP28 | c.533G>C p.S178T (on ENST00000383472 / NM_001366230.1; = p.S19T on NM_001010000.3) | Missense Mutation (SNP) | VAF 144/280 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV51646723; called by muse, mutect2, varscan2
- ARID1A | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 403/703 reads (57%) | catalogued as COSV61374548; called by muse, mutect2, varscan2
- ATRX | c.6678G>C p.R2226S | Missense Mutation (SNP) | VAF 173/585 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV64873079; called by muse, mutect2, varscan2
- BRWD3 | c.4906G>A p.V1636I | Missense Mutation (SNP) | VAF 453/1066 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs151186096, COSV64751960; called by muse, mutect2, varscan2
- CACNA1E | c.4102G>T p.V1368F | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV62402477; called by muse, mutect2, varscan2
- CACNG6 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.796); catalogued as COSV53165882; called by muse, varscan2
- CAND1 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV73338604; called by muse, varscan2
- CLASP1 | c.4217C>T p.A1406V | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs780921353, COSV104377181; called by mutect2, varscan2
- CNTNAP5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 204/386 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV101443307; called by muse, mutect2, varscan2
- CRHR2 | c.917+2T>A p.X306_splice | Splice Site (SNP) | VAF 107/397 reads (27%) | catalogued as rs938752942; called by muse, mutect2, varscan2
- CSF1R | c.1221A>G p.I407M | Missense Mutation (SNP) | VAF 110/157 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs757033979; called by muse, mutect2, varscan2
- CXorf66 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100983891; called by muse, mutect2, varscan2
- CYP27A1 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 253/590 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs755452918; called by muse, mutect2, varscan2
- DGKK | c.1944C>A p.H648Q | Missense Mutation (SNP) | VAF 107/516 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as COSV65709815; called by muse, mutect2, varscan2
- DNAJB8 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV59879212; called by muse, mutect2, varscan2
- EVX2 | c.1392C>A p.S464R | Missense Mutation (SNP) | VAF 121/213 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs1364083666; called by muse, mutect2, varscan2
- F8 | c.5587-2A>C p.X1863_splice | Splice Site (SNP) | VAF 242/657 reads (37%) | catalogued as CS083226, CS0910299; called by muse, mutect2, varscan2
- FAM135B | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 132/530 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425531; called by muse, mutect2, varscan2
- FLNA | c.5404G>T p.G1802C (on ENST00000369850 / NM_001110556.2; = p.G1794C on NM_001456.3) | Missense Mutation (SNP) | VAF 250/741 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100774704; called by muse, mutect2, varscan2
- FLNA | c.2193C>G p.Y731* | Nonsense Mutation (SNP) | VAF 181/564 reads (32%) | catalogued as CM098088, CM1212810; called by muse, mutect2, varscan2
- FSHR | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 204/586 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV58626179; called by muse, mutect2, varscan2
- GAGE10 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 325/607 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV101339907; called by muse, mutect2, varscan2
- GATAD2A | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs200662477; called by muse, mutect2, varscan2
- GOSR1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1298435389; called by muse, mutect2, varscan2
- GPNMB | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 264/594 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV51701329; called by muse, mutect2, varscan2
- GRIK3 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 233/429 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV66136878; called by muse, mutect2, varscan2
- GRM1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51110749; called by muse, mutect2, varscan2
- GTF3C1 | c.5389G>T p.G1797C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649129; called by muse, mutect2, varscan2
- HBD | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 350/504 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53082591; called by muse, mutect2, varscan2
- HHIP | c.1646del p.G549Vfs*11 | Frame Shift Del (DEL) | VAF 198/313 reads (63%) | catalogued as COSV99667686; called by mutect2, pindel, varscan2
- HIVEP2 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs967871362; called by muse, mutect2, varscan2
- ITGB2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 145/455 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100185712; called by muse, mutect2, varscan2
- KIAA1210 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 202/496 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV68179481; called by muse, mutect2, varscan2
- KIF9 | c.1512C>A p.L504= | Splice Region (SNP) | VAF 77/98 reads (79%) | catalogued as COSV55519396; called by muse, mutect2, varscan2
- KMT2D | c.6505G>C p.A2169P | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56412943; called by muse, mutect2
- KRT79 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57940361; called by muse, mutect2, varscan2
- MARCO | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs142540932; called by muse, mutect2, varscan2
- MTG2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV63695560; called by muse, mutect2, varscan2
- MVK | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 242/921 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1191193699; called by muse, mutect2, varscan2
- NCAM2 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 58/143 reads (41%) | catalogued as COSV53072285, COSV53098666, COSV99525968; called by muse, mutect2, varscan2
- NEB | c.3289G>T p.G1097W | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424117; called by muse, mutect2, varscan2
- OAS3 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764355784; called by muse, varscan2
- OR2T8 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1169060768; called by muse, mutect2, varscan2
- PASD1 | c.1752G>C p.Q584H | Missense Mutation (SNP) | VAF 461/1063 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100949017, COSV64856831; called by muse, mutect2, varscan2
- PCARE | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs760317889, COSV59054144; called by muse, mutect2, varscan2
- POM121C | c.904G>C p.V302L (on ENST00000607367; = p.V60L on NM_001099415.3) | Missense Mutation (SNP) | VAF 162/732 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs1385148299, COSV99992573; called by muse, mutect2, varscan2
- PRR30 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV53208351; called by muse, mutect2, varscan2
- RAPGEF4 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 270/560 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs376497880; called by muse, mutect2, varscan2
- RGS5 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV100008939; called by muse, mutect2, varscan2
- RYR2 | c.12568G>A p.V4190M | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1308975705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFXN4 | c.584G>A p.W195* | Nonsense Mutation (SNP) | VAF 161/475 reads (34%) | catalogued as COSV57459819; called by muse, mutect2, varscan2
- SI | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 370/721 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV100014642; called by muse, mutect2, varscan2
- SIKE1 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 199/409 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1240146949; called by muse, mutect2, varscan2
- SLC39A4 | c.730C>T p.R244W (on ENST00000301305 / NM_001374839.1; = p.R219W on NM_017767.3) | Missense Mutation (SNP) | VAF 161/313 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs190347138; called by muse, mutect2, varscan2
- SLFN13 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 351/726 reads (48%) | catalogued as COSV53193325; called by muse, mutect2, varscan2
- SPATA31A6 | c.3812G>A p.S1271N | Missense Mutation (SNP) | VAF 104/776 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs779604548; called by muse, mutect2, varscan2
- STYXL2 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs370561353, COSV54811117; called by muse, mutect2, varscan2
- SYP | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54294813; called by muse, varscan2
- SZT2 | c.7147G>C p.A2383P (on ENST00000634258 / NM_001365999.1; = p.A2326P on NM_015284.4) | Missense Mutation (SNP) | VAF 121/413 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV65168201; called by muse, mutect2, varscan2
- TBC1D2 | c.2383G>T p.V795L | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV59782306, COSV59782613; called by muse, mutect2, varscan2
- TBC1D30 | c.2165C>T p.T722M (on ENST00000542120; = p.T559M on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/834 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs959797298; called by muse, mutect2
- TBL2 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 125/459 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs782071345; called by muse, mutect2, varscan2
- TERT | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV57216249; called by muse, mutect2, varscan2
- TEX13C | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 242/611 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1174656356, COSV64020770; called by muse, mutect2, varscan2
- TPO | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.456); catalogued as COSV61095304; called by muse, mutect2, varscan2
- TRPC5 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 209/486 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV53297331; called by muse, mutect2, varscan2
- TTLL9 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs568245486, COSV52431327; called by muse, mutect2, varscan2
- TTN | c.24534G>C p.E8178D (on ENST00000591111; = p.E7251D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/550 reads (22%) | PolyPhen benign (0.019); catalogued as COSV100636337; called by muse, mutect2, varscan2
- UBR2 | c.3587G>T p.R1196L | Missense Mutation (SNP) | VAF 183/267 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV65750622; called by muse, mutect2, varscan2
- URAD | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 79/97 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60380789, COSV60380964; called by muse, mutect2, varscan2
- VWDE | c.4439A>G p.Y1480C | Missense Mutation (SNP) | VAF 306/582 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51724296; called by muse, mutect2, varscan2
- ZDHHC11B | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 116/404 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs756278131; called by muse, mutect2, varscan2
- ZNF28 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 85/526 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs779634852, COSV60423052, COSV60424999; called by muse, mutect2, varscan2
- ZNF438 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754239573, COSV100061522; called by mutect2, varscan2
- ZNF835 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV73379735; called by muse, mutect2, varscan2
- ABCA12 | c.5705G>A p.S1902N (on ENST00000272895 / NM_173076.3; = p.S1584N on NM_015657.3) | Missense Mutation (SNP) | VAF 147/724 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ABCA13 | c.2152A>G p.M718V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG2 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACADL | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL1 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 100/344 reads (29%) | called by muse, varscan2
- AKR1D1 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 167/617 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANK2 | c.1240A>T p.M414L | Missense Mutation (SNP) | VAF 805/988 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARHGEF5 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by mutect2, varscan2
- ARID4A | c.3694T>C p.S1232P | Missense Mutation (SNP) | VAF 170/318 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP1A4 | c.1948G>T p.V650F | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ATP23 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- ATRN | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- BAHCC1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by mutect2, varscan2
- BCORL1 | c.2905C>A p.Q969K | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BEST2 | c.28del p.A10Rfs*37 | Frame Shift Del (DEL) | VAF 89/284 reads (31%) | called by mutect2, pindel, varscan2
- BIRC6 | c.6337C>A p.P2113T | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPIFA1 | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 277/558 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- BUB3 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C3 | c.2653A>C p.T885P | Missense Mutation (SNP) | VAF 147/746 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- C5orf24 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 319/475 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNG7 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 176/429 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAND1 | c.3361-1G>T p.X1121_splice | Splice Site (SNP) | VAF 76/234 reads (32%) | called by muse, mutect2, varscan2
- CASP3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CAT | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 371/527 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CCDC110 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CCDC168 | c.13880C>A p.T4627K | Missense Mutation (SNP) | VAF 147/203 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CDC42EP5 | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH19 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDHR2 | c.195del p.N66Mfs*14 | Frame Shift Del (DEL) | VAF 213/381 reads (56%) | called by mutect2, pindel, varscan2
- CDK12 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 112/216 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CEP170 | c.2865G>T p.K955N | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHRNA7 | c.179T>A p.L60Q | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CHST1 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CNTNAP3 | c.1652G>C p.C551S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- COL14A1 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- COL16A1 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A3 | c.1945del p.Q649Rfs*66 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- COL6A2 | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- COLEC12 | c.1954-2A>T p.X652_splice | Splice Site (SNP) | VAF 111/375 reads (30%) | called by muse, mutect2, varscan2
- CREB3L3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CRHR1 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CRYBG1 | c.4900C>A p.P1634T | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CTPS2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.3387G>C p.M1129I | Missense Mutation (SNP) | VAF 203/324 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMAP1 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DNM1 | c.2303T>C p.V768A | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- DPY19L2 | c.1385C>A p.A462D | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DYNC1H1 | c.10045C>G p.P3349A | Missense Mutation (SNP) | VAF 169/282 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDC3 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- EEF1A2 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ELFN1 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD4 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 481/673 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EPB41L5 | c.709G>T p.V237F | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EPOP | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERICH4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 384/824 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- F8 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 192/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM71E2 | c.1996T>A p.L666M | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.5339A>T p.E1780V | Missense Mutation (SNP) | VAF 188/258 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCN2 | c.376T>G p.C126G | Missense Mutation (SNP) | VAF 185/420 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FOXO4 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 347/850 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- FUT9 | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GPR143 | c.157del p.R53Gfs*34 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- GRIA2 | c.2570C>A p.P857Q | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- GSDMB | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 126/471 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTDC1 | c.224_235del p.A75_P78del | In Frame Del (DEL) | VAF 96/244 reads (39%) | called by mutect2, pindel, varscan2
- HCFC1 | c.2957C>A p.T986N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HECTD4 | c.11273A>G p.E3758G | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HELZ | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 106/419 reads (25%) | called by muse, mutect2, varscan2
- HIP1R | c.835A>T p.I279F | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIVEP3 | c.2012T>G p.I671S | Missense Mutation (SNP) | VAF 159/559 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HPN | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IGKV3-7 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- IGKV3D-7 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 78/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAK2 | c.2088A>T p.K696N | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH2 | c.2461G>T p.D821Y | Missense Mutation (SNP) | VAF 250/503 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KCNK6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 149/457 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIAA0319 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 217/271 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1671 | c.5182G>T p.D1728Y | Missense Mutation (SNP) | VAF 132/165 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4A | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LACTBL1 | c.185G>C p.G62A (on ENST00000618559; = p.G91A on NM_001289974.2) | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LMX1A | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 96/170 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0.055); called by muse, mutect2
- LRCH2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.10559T>C p.F3520S | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LTBP4 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 127/348 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by mutect2, varscan2
- MACF1 | c.17744C>T p.P5915L (on ENST00000372915; = p.P3960L on NM_012090.5) | Missense Mutation (SNP) | VAF 147/622 reads (24%) | called by muse, mutect2, varscan2
- MAGEA1 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 206/536 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MAGEA11 | c.900T>A p.D300E | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MAGEA3 | c.-67C>A | Splice Region (SNP) | VAF 219/1022 reads (21%) | called by muse, mutect2, varscan2
- MAGEB10 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 98/315 reads (31%) | called by muse, mutect2, varscan2
- MATN1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD1 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- MRO | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, varscan2
- MUC17 | c.5432C>A p.T1811K | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MUC21 | c.435T>G p.S145R | Missense Mutation (SNP) | VAF 552/728 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, varscan2
- MYH14 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 173/447 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2
- MYH7B | c.4603G>C p.G1535R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NADK2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2
- NAV3 | c.5892T>A p.Y1964* (on ENST00000397909 / NM_001024383.2; = p.Y1942* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 51/194 reads (26%) | called by muse, varscan2
- NBPF3 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NEU4 | c.713A>T p.Y238F (on ENST00000391969 / NM_001167602.3; = p.Y250F on NM_080741.4) | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.1873G>T p.A625S | Missense Mutation (SNP) | VAF 165/344 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NIPBL | c.7147A>T p.R2383* | Nonsense Mutation (SNP) | VAF 349/924 reads (38%) | called by muse, mutect2, varscan2
- NKTR | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 135/181 reads (75%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NLGN3 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NOC2L | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 139/564 reads (25%) | called by muse, mutect2, varscan2
- NOL9 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.905T>A p.M302K | Missense Mutation (SNP) | VAF 218/424 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- NUP133 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- OR12D3 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 172/569 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5AC2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 26/39 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8G5 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 356/534 reads (67%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH15 | c.4823C>A p.S1608Y | Missense Mutation (SNP) | VAF 215/654 reads (33%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PCDH15 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 200/549 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB4 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 324/459 reads (71%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PCDHB8 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 515/1349 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PCYOX1L | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 137/204 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE6C | c.1936A>T p.S646C | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- PDHA2 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 207/364 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDK3 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFAS | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 92/143 reads (64%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKL | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 118/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.1008A>T p.T336= | Splice Region (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- PLCG2 | c.3059A>T p.Y1020F | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLCXD3 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 161/363 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 102/387 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PLXNC1 | c.3250A>C p.R1084= | Splice Region (SNP) | VAF 52/177 reads (29%) | called by muse, mutect2, varscan2
- PNMA2 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 147/205 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R9A | c.2797A>G p.S933G | Missense Mutation (SNP) | VAF 125/540 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PRMT8 | c.1101+1del | Frame Shift Del (DEL) | VAF 187/471 reads (40%) | called by mutect2, pindel, varscan2
- PRSS55 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 98/137 reads (72%) | called by muse, mutect2, varscan2
- PTGER4 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 174/445 reads (39%) | called by muse, mutect2, varscan2
- PTPRS | c.2440A>G p.M814V | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAB40A | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 254/783 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RABGAP1L | c.1051G>T p.A351S (on ENST00000489615 / NM_001243765.2; = p.A234S on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 264/529 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RB1 | c.1351_1359del p.R451_Y453del | In Frame Del (DEL) | VAF 175/314 reads (56%) | called by mutect2, pindel, varscan2
- RBM46 | c.181T>A p.C61S | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RYR2 | c.6239T>C p.L2080P | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBK3 | c.336dup p.Y113Lfs*55 | Frame Shift Ins (INS) | VAF 72/218 reads (33%) | called by mutect2, pindel, varscan2
- SGO2 | c.1440A>C p.E480D | Missense Mutation (SNP) | VAF 123/249 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SHANK1 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SHC2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SHROOM2 | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC38A11 | c.817G>T p.G273C (on ENST00000409149 / NM_001351539.1; = p.G251C on NM_173512.2) | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SLC46A2 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A3 | c.3139A>G p.T1047A | Missense Mutation (SNP) | VAF 97/604 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SON | c.5564A>G p.K1855R | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPATA31A3 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 461/1654 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- STK36 | c.1568G>T p.W523L | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STMN3 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNRG | c.3214A>T p.R1072W | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAB3 | c.204A>T p.R68S | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TBC1D16 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TBR1 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX20 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 226/487 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCP11X2 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- TECTB | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TEDC1 | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- TEDC1 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TENT5A | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- THBD | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.4810G>A p.G1604R (on ENST00000272643; = p.G1602R on NM_001316349.2) | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM143 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 105/284 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOX2 | c.629C>T p.P210L (on ENST00000358131 / NM_001098798.2; = p.P159L on NM_032883.3) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TP53 | c.778_782+19del p.X260_splice | Splice Site (DEL) | VAF 141/237 reads (59%) | called by mutect2, pindel, varscan2
- TPD52L3 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 438/837 reads (52%) | called by muse, mutect2, varscan2
- TRAV19 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TRPA1 | c.1358del p.A453Efs*17 | Frame Shift Del (DEL) | VAF 383/735 reads (52%) | called by mutect2, varscan2
- TTC4 | c.99C>A p.D33E | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.40796G>T p.W13599L (on ENST00000591111; = p.W6175L on NM_003319.4) | Missense Mutation (SNP) | VAF 292/594 reads (49%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.33799C>T p.P11267S (on ENST00000591111; = p.P10340S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.29519G>T p.G9840V (on ENST00000591111; = p.G8913V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/401 reads (23%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.29518G>T p.G9840C (on ENST00000591111; = p.G8913C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/406 reads (24%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.9350C>A p.P3117Q (on ENST00000591111; = p.P3071Q on NM_003319.4) | Missense Mutation (SNP) | VAF 176/642 reads (27%) | PolyPhen benign (0.007); called by muse, mutect2
- TXK | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 116/169 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAC1 | c.1147A>T p.M383L | Missense Mutation (SNP) | VAF 182/389 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBAP1L | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- UCK2 | c.528G>T p.R176S | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13A | c.2337G>A p.M779I | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- URB1 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP11 | c.2237A>T p.D746V (on ENST00000218348; = p.D703V on NM_001371072.1) | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WIZ | c.5577del p.H1860Tfs*5 (on ENST00000673675 / NM_001371589.1; = p.H765Tfs*5 on NM_021241.3) | Frame Shift Del (DEL) | VAF 91/361 reads (25%) | called by mutect2, pindel, varscan2
- WNK2 | c.5948G>C p.R1983P (on ENST00000297954 / NM_001282394.1; = p.R1946P on NM_006648.3) | Missense Mutation (SNP) | VAF 115/503 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XAB2 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- XKR8 | c.1077T>G p.S359R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.2308C>G p.P770A | Missense Mutation (SNP) | VAF 198/732 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- ZDHHC6 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ZFHX4 | c.5310G>A p.M1770I | Missense Mutation (SNP) | VAF 103/357 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZFHX4 | c.9436C>A p.P3146T | Missense Mutation (SNP) | VAF 101/185 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZFR | c.2153G>T p.R718L | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZFYVE16 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 116/167 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ZNF521 | c.2320A>T p.N774Y | Missense Mutation (SNP) | VAF 315/570 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF654 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); called by mutect2, varscan2
- ZNF676 | c.563T>A p.L188Q (on ENST00000650058; = p.L156Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF831 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ADGB | c.912C>A p.A304= | Silent (SNP) | VAF 94/284 reads (33%) | called by muse, varscan2
- ANKRD28 | c.2796T>C p.V932= | Silent (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- APOBEC4 | c.660G>A p.L220= | Silent (SNP) | VAF 124/442 reads (28%) | called by muse, mutect2
- BBS12 | c.870A>T p.V290= | Silent (SNP) | VAF 192/244 reads (79%) | called by muse, mutect2, varscan2
- BCAR1 | c.1203T>C p.D401= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- BMP7 | c.720G>T p.R240= | Silent (SNP) | VAF 111/455 reads (24%) | catalogued as rs1472375458, COSV101215858; called by muse, mutect2, varscan2
- C12orf42 | c.66A>T p.A22= | Silent (SNP) | VAF 67/324 reads (21%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.1917G>T p.L639= | Silent (SNP) | VAF 202/279 reads (72%) | catalogued as COSV99877079; called by muse, mutect2, varscan2
- CDH11 | c.2097G>A p.E699= | Silent (SNP) | VAF 70/218 reads (32%) | called by muse, mutect2, varscan2
- CDH9 | c.930A>G p.G310= | Silent (SNP) | VAF 120/574 reads (21%) | called by muse, varscan2
- CDHR1 | c.585G>T p.G195= | Silent (SNP) | VAF 166/492 reads (34%) | called by muse, mutect2, varscan2
- CDYL2 | c.465G>A p.G155= | Silent (SNP) | VAF 88/300 reads (29%) | called by muse, mutect2, varscan2
- CEACAM8 | c.60C>T p.L20= | Silent (SNP) | VAF 89/288 reads (31%) | called by muse, mutect2, varscan2
- CEP89 | c.912G>C p.L304= | Silent (SNP) | VAF 77/517 reads (15%) | called by muse, mutect2, varscan2
- CPA2 | c.6C>T p.A2= | Silent (SNP) | VAF 234/486 reads (48%) | called by muse, mutect2, varscan2
- CTDP1 | c.747C>T p.S249= | Silent (SNP) | VAF 222/452 reads (49%) | called by muse, mutect2, varscan2
- DGKK | c.1635G>T p.L545= | Silent (SNP) | VAF 132/623 reads (21%) | catalogued as COSV101052884; called by muse, mutect2, varscan2
- DMXL1 | c.6030A>G p.T2010= | Silent (SNP) | VAF 129/164 reads (79%) | catalogued as rs1163769405; called by muse, mutect2, varscan2
- EIF1B | c.288T>C p.F96= | Silent (SNP) | VAF 131/185 reads (71%) | called by muse, mutect2, varscan2
- F8 | c.717G>A p.R239= | Silent (SNP) | VAF 220/1027 reads (21%) | called by muse, mutect2, varscan2
- FAM135B | c.3603C>T p.H1201= | Silent (SNP) | VAF 110/267 reads (41%) | called by muse, mutect2, varscan2
- FAM155B | c.240C>A p.P80= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- FBP1 | c.900G>A p.K300= | Silent (SNP) | VAF 125/456 reads (27%) | catalogued as COSV64690056; called by muse, mutect2, varscan2
- FRMPD1 | c.4170C>A p.T1390= | Silent (SNP) | VAF 123/224 reads (55%) | called by muse, mutect2, varscan2
- FTCDNL1 | c.222C>A p.R74= | Silent (SNP) | VAF 104/426 reads (24%) | called by muse, mutect2, varscan2
- GDPD2 | c.1002G>A p.T334= | Silent (SNP) | VAF 143/352 reads (41%) | catalogued as rs759072212; called by muse, mutect2, varscan2
- GOLGA8M | c.1050T>C p.L350= | Silent (SNP) | VAF 259/766 reads (34%) | called by muse, varscan2
- GRIN3A | c.72G>T p.V24= | Silent (SNP) | VAF 133/506 reads (26%) | called by muse, mutect2, varscan2
- HCFC1 | c.669G>T p.G223= | Silent (SNP) | VAF 130/411 reads (32%) | called by muse, mutect2, varscan2
- HK3 | c.2424C>T p.A808= | Silent (SNP) | VAF 77/102 reads (75%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.210C>A p.I70= | Silent (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.18C>T p.P6= | Silent (SNP) | VAF 106/390 reads (27%) | catalogued as rs569206745; called by muse, mutect2, varscan2
- IGSF21 | c.132G>A p.L44= | Silent (SNP) | VAF 167/347 reads (48%) | catalogued as COSV52138452; called by muse, mutect2, varscan2
- IRS2 | c.2796G>T p.S932= | Silent (SNP) | VAF 37/46 reads (80%) | called by muse, mutect2, varscan2
- JADE2 | c.726G>T p.L242= | Silent (SNP) | VAF 57/74 reads (77%) | called by muse, mutect2, varscan2
- KBTBD8 | c.1269T>C p.T423= | Silent (SNP) | VAF 234/327 reads (72%) | catalogued as rs764213232; called by muse, mutect2, varscan2
- KMT2D | c.1782G>T p.P594= | Silent (SNP) | VAF 359/678 reads (53%) | called by muse, mutect2, varscan2
- LIG4 | c.1959C>T p.N653= | Silent (SNP) | VAF 83/386 reads (22%) | called by muse, mutect2, varscan2
- LINGO2 | c.1275G>A p.G425= | Silent (SNP) | VAF 78/247 reads (32%) | catalogued as rs760521373; called by muse, mutect2, varscan2
- LRFN4 | c.333G>A p.L111= | Silent (SNP) | VAF 48/63 reads (76%) | called by muse, mutect2, varscan2
- MAGEB6B | c.1164A>C p.P388= | Silent (SNP) | VAF 75/235 reads (32%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1875C>T p.H625= | Silent (SNP) | VAF 182/240 reads (76%) | called by muse, mutect2, varscan2
- MCF2 | c.1089C>A p.L363= | Silent (SNP) | VAF 74/178 reads (42%) | catalogued as COSV58478036; called by muse, mutect2, varscan2
- MEIOC | c.1101C>T p.T367= | Silent (SNP) | VAF 63/345 reads (18%) | catalogued as COSV100740306; called by muse, mutect2, varscan2
- METTL11B | c.375C>A p.S125= | Silent (SNP) | VAF 292/556 reads (53%) | catalogued as COSV63030163; called by muse, mutect2, varscan2
- NR3C2 | c.2460A>G p.K820= | Silent (SNP) | VAF 471/565 reads (83%) | catalogued as COSV100679026; called by muse, mutect2, varscan2
- NR4A3 | c.1014G>A p.K338= | Silent (SNP) | VAF 46/238 reads (19%) | called by muse, mutect2, varscan2
- NXNL1 | c.315T>C p.D105= | Silent (SNP) | VAF 93/273 reads (34%) | called by muse, mutect2, varscan2
- OGDHL | c.2793A>G p.A931= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- OR10A7 | c.630C>T p.P210= | Silent (SNP) | VAF 157/744 reads (21%) | catalogued as rs193164210; called by muse, mutect2, varscan2
- OR2T8 | c.483C>G p.T161= | Silent (SNP) | VAF 31/320 reads (10%) | called by muse, varscan2
- OR6C2 | c.660C>A p.V220= | Silent (SNP) | VAF 118/425 reads (28%) | called by muse, mutect2, varscan2
- PCDH1 | c.3234A>G p.R1078= | Silent (SNP) | VAF 69/90 reads (77%) | called by muse, mutect2, varscan2
- PDZD4 | c.1512G>C p.R504= | Silent (SNP) | VAF 48/113 reads (42%) | called by muse, mutect2, varscan2
- PERM1 | c.1888C>A p.R630= | Silent (SNP) | VAF 72/274 reads (26%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1752C>A p.V584= | Silent (SNP) | VAF 99/379 reads (26%) | catalogued as COSV100325227; called by muse, mutect2, varscan2
- PRAG1 | c.1986C>T p.P662= | Silent (SNP) | VAF 211/283 reads (75%) | called by muse, mutect2, varscan2
- PTPRM | c.159C>T p.T53= | Silent (SNP) | VAF 211/448 reads (47%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.591C>T p.P197= | Silent (SNP) | VAF 114/171 reads (67%) | catalogued as rs772031702; called by muse, mutect2, varscan2
- SELP | c.1650A>G p.E550= | Silent (SNP) | VAF 106/192 reads (55%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.1293G>A p.K431= | Silent (SNP) | VAF 84/166 reads (51%) | called by muse, mutect2, varscan2
- SERPINA3 | c.267G>A p.L89= | Silent (SNP) | VAF 196/324 reads (60%) | catalogued as COSV101261670; called by muse, mutect2, varscan2
- SH2B1 | c.558G>A p.E186= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs750308392; called by muse, mutect2, varscan2
- SI | c.180A>G p.S60= | Silent (SNP) | VAF 176/408 reads (43%) | called by muse, varscan2
- SLC14A2 | c.2103C>A p.P701= | Silent (SNP) | VAF 103/348 reads (30%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1224C>T p.A408= | Silent (SNP) | VAF 98/296 reads (33%) | called by muse, mutect2, varscan2
- SLC44A5 | c.1092T>A p.I364= | Silent (SNP) | VAF 116/219 reads (53%) | called by muse, mutect2, varscan2
- SLFNL1 | c.87C>A p.P29= | Silent (SNP) | VAF 175/305 reads (57%) | catalogued as rs549710394, COSV57235660; called by muse, mutect2, varscan2
- SLITRK4 | c.556C>A p.R186= | Silent (SNP) | VAF 178/394 reads (45%) | called by muse, mutect2, varscan2
- SPTA1 | c.2946C>A p.V982= | Silent (SNP) | VAF 159/559 reads (28%) | catalogued as COSV63749055, COSV63750775; called by muse, mutect2, varscan2
- SULT6B1 | c.489C>A p.G163= (on ENST00000535679 / NM_001367551.1; = p.G125= on NM_001032377.2) | Silent (SNP) | VAF 64/348 reads (18%) | called by muse, mutect2
- TBR1 | c.1926G>T p.P642= | Silent (SNP) | VAF 201/416 reads (48%) | called by muse, mutect2, varscan2
- TNR | c.1227C>A p.A409= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV54878950; called by muse, mutect2, varscan2
- TTN | c.15603C>T p.G5201= (on ENST00000591111; = p.G4274= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/159 reads (57%) | catalogued as rs778313904; called by muse, mutect2, varscan2
- ZNF585A | c.798C>A p.G266= (on ENST00000292841 / NM_001288800.2; = p.G211= on NM_152655.3) | Silent (SNP) | VAF 132/811 reads (16%) | called by muse, mutect2, varscan2
- AC133065.1 | n.439-1465G>A | Intron (SNP) | VAF 59/142 reads (42%) | catalogued as rs776905914; called by muse, mutect2, varscan2
- AMPH | c.1182+1242G>C | Intron (SNP) | VAF 224/413 reads (54%) | catalogued as COSV100343337; called by muse, mutect2, varscan2
- ANKZF1 | c.149-83T>A | Intron (SNP) | VAF 92/194 reads (47%) | called by muse, mutect2, varscan2
- ARGLU1 | c.573+187G>T | Intron (SNP) | VAF 236/285 reads (83%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4242G>T | Intron (SNP) | VAF 304/853 reads (36%) | called by muse, mutect2, varscan2
- ARSA | c.*45G>T | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- BAZ1A | c.537-5815C>T | Intron (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- BLOC1S6 | c.225-5165T>A | Intron (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- BRWD3 | c.2231+50G>T | Intron (SNP) | VAF 102/238 reads (43%) | called by muse, mutect2, varscan2
- CCDC15 | c.2586-25G>T | Intron (SNP) | VAF 36/47 reads (77%) | called by muse, mutect2, varscan2
- CDC123 | c.*155dup | 3'UTR (INS) | VAF 34/87 reads (39%) | called by mutect2, varscan2
- CHMP2B | c.425-42G>T | Intron (SNP) | VAF 183/248 reads (74%) | catalogued as rs756914093; called by muse, mutect2, varscan2
- COL25A1 | c.1845+36T>C | Intron (SNP) | VAF 148/948 reads (16%) | called by muse, mutect2, varscan2
- DNAH10 | c.1816-2580G>T | Intron (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- DNMT1 | c.2847-51A>T | Intron (SNP) | VAF 235/553 reads (42%) | called by muse, mutect2, varscan2
- GLUD2 | c.-6G>C | 5'UTR (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- HCFC1 | c.4498-22C>A | Intron (SNP) | VAF 159/571 reads (28%) | called by muse, mutect2, varscan2
- IAPP | c.80+237C>A | Intron (SNP) | VAF 84/190 reads (44%) | called by muse, varscan2
- KATNIP | c.*9G>A | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- KYAT3 | c.453+189C>G | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2
- LTBP1 | c.1034-324G>T | Intron (SNP) | VAF 137/641 reads (21%) | called by muse, mutect2, varscan2
- LYPD3 | c.383-144C>T | Intron (SNP) | VAF 124/350 reads (35%) | called by muse, mutect2
- METTL15 | c.779-2293G>C | Intron (SNP) | VAF 52/158 reads (33%) | called by muse, mutect2, varscan2
- MIR508 | n.75dup | RNA (INS) | VAF 84/286 reads (29%) | called by pindel, varscan2
- MIR508 | n.22G>T | RNA (SNP) | VAF 143/363 reads (39%) | called by muse, varscan2
- MPZ | chr1:161309960 C>A | 5'Flank (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- MUC19 | c.516+12G>A | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- NCALD | c.-1G>T | 5'UTR (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.951C>G | RNA (SNP) | VAF 148/691 reads (21%) | called by muse, mutect2, varscan2
- NT5DC3 | chr12:103841541 G>C | 5'Flank (SNP) | VAF 140/363 reads (39%) | called by muse, mutect2, varscan2
- NTNG2 | c.1054+861C>A | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- PDE4C | c.-209-100G>T | Intron (SNP) | VAF 132/393 reads (34%) | called by muse, varscan2
- PHOSPHO1 | c.46-705G>T | Intron (SNP) | VAF 98/185 reads (53%) | called by muse, mutect2, varscan2
- PIPSL | n.1355C>A | RNA (SNP) | VAF 150/425 reads (35%) | called by muse, mutect2, varscan2
- PITX2 | c.185-959C>A | Intron (SNP) | VAF 452/572 reads (79%) | catalogued as rs769617540; called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65762C>A | Intron (SNP) | VAF 130/438 reads (30%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.-7A>C | 5'UTR (SNP) | VAF 245/622 reads (39%) | called by muse, mutect2, varscan2
- PROC | c.400+41G>C | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.608C>T | RNA (SNP) | VAF 385/935 reads (41%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 24/386 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- RNA5-8SP2 | chr16:34159635 G>T | 5'Flank (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- SEC1P | n.604C>T | RNA (SNP) | VAF 136/366 reads (37%) | catalogued as rs762401617; called by muse, mutect2, varscan2
- SLC6A8 | c.778-39G>T | Intron (SNP) | VAF 264/626 reads (42%) | catalogued as rs782063195; called by muse, mutect2, varscan2
- SLIT3 | c.1459+4572G>T | Intron (SNP) | VAF 187/270 reads (69%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26327G>A | Intron (SNP) | VAF 99/293 reads (34%) | catalogued as rs771775415; called by muse, mutect2, varscan2
- SSPOP | n.8966G>A | RNA (SNP) | VAF 15/62 reads (24%) | catalogued as rs763693478, COSV65132883, COSV65139067; called by mutect2, varscan2
- SSPOP | n.11292G>T | RNA (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- STK11IP | c.946-29A>T | Intron (SNP) | VAF 171/379 reads (45%) | called by muse, mutect2, varscan2
- SUN1 | c.659-381A>G | Intron (SNP) | VAF 83/152 reads (55%) | called by muse, mutect2, varscan2
- TES | c.1077+78A>G | Intron (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
- THY1 | c.*80C>T | 3'UTR (SNP) | VAF 120/168 reads (71%) | called by muse, varscan2
- TNFRSF4 | c.269-177G>T | Intron (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- TTC14 | c.858-42del | Intron (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- TTC21B | c.*18G>C | 3'UTR (SNP) | VAF 154/319 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.10360+3231del | Intron (DEL) | VAF 141/780 reads (18%) | catalogued as COSV59902704; called by mutect2, pindel, varscan2
- U8 | chr15:30113947 A>G | 3'Flank (SNP) | VAF 72/231 reads (31%) | called by muse, mutect2, varscan2
- UTP14A | c.-26C>T | 5'UTR (SNP) | VAF 195/477 reads (41%) | called by muse, mutect2, varscan2
- VWA3B | c.2673+5534C>G | Intron (SNP) | VAF 99/524 reads (19%) | catalogued as COSV68246398; called by muse, mutect2, varscan2
- WASHC3 | c.151-4169G>T | Intron (SNP) | VAF 54/240 reads (23%) | called by mutect2, varscan2
- WNK4 | c.2295+130_2295+131insAT | Intron (INS) | VAF 92/292 reads (32%) | called by pindel, varscan2
- ZNF99 | c.*596G>T | 3'UTR (SNP) | VAF 113/290 reads (39%) | called by muse, mutect2, varscan2
